Somatic mutation profile of tumor specimen MP2PRT-PARNFB-TMP1-A (aliquot MP2PRT-PARNFB-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARNFB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.8 years (3,205 days).
Specimen MP2PRT-PARNFB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58ebe75d-a4be-4bca-8d89-27eab272e50b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARNFB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARNFB-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f9b4f20-9607-4b65-a2a0-11295b67e6f9

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 2, In Frame Ins 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DENND6B | c.1685G>C p.R562P | Missense Mutation (SNP) | VAF 32/560 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV100834028, COSV100834218; called by muse, mutect2
- GBA3 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 75/390 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs745773168, COSV72438501; called by muse, mutect2
- HMGCLL1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs748496553; called by muse, mutect2, varscan2
- RIMS2 | c.798G>A p.M266I (on ENST00000666250 / NM_001348490.2; = p.M74I on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.993); catalogued as rs139492859; called by muse, mutect2, varscan2
- RNF224 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 293/640 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1451953510, COSV62986509; called by muse, mutect2, varscan2
- SERPINA10 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 302/641 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs370404211; called by muse, mutect2, varscan2
- BAZ1A | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 26/396 reads (7%) | called by muse, mutect2
- FSTL5 | c.237C>A p.S79R | Missense Mutation (SNP) | VAF 17/430 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2
- SETD2 | c.6220A>T p.K2074* | Nonsense Mutation (SNP) | VAF 88/562 reads (16%) | called by muse, mutect2, varscan2
- SETD2 | c.5257_5258insTGATAGGGC p.T1753delinsMIGP | In Frame Ins (INS) | VAF 68/388 reads (18%) | called by mutect2, pindel*, varscan2*
- SETD2 | c.4282_4283insCCTC p.R1428Tfs*27 | Frame Shift Ins (INS) | VAF 72/551 reads (13%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.3930C>T p.N1310= | Silent (SNP) | VAF 170/392 reads (43%) | catalogued as rs141717162; called by muse, varscan2
- COL16A1 | c.2736C>A p.P912= | Silent (SNP) | VAF 96/529 reads (18%) | catalogued as COSV54712474; called by muse, mutect2, varscan2
- TMEM238L | c.121C>T p.L41= | Silent (SNP) | VAF 243/478 reads (51%) | called by muse, mutect2, varscan2
- DCHS2 | n.660G>A | RNA (SNP) | VAF 57/265 reads (22%) | catalogued as rs536580730, COSV59724334, COSV99044894; called by muse, mutect2, varscan2
- NDUFV3 | c.170-5184A>T | Intron (SNP) | VAF 20/623 reads (3%) | called by muse, mutect2
